Somatic mutation profile of tumor specimen TCGA-DA-A95Y-06A (aliquot TCGA-DA-A95Y-06A-11D-A372-08) from TCGA case TCGA-DA-A95Y, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.4 years (25,354 days).
Specimen TCGA-DA-A95Y-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e20dc94-8909-4fba-9580-6c7ea5197e2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A95Y-10A (Blood Derived Normal), aliquot TCGA-DA-A95Y-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6b2f72a-fd8f-42a0-9b7f-d97a119df7b1

The open-access MAF lists 486 somatic variants for this specimen: 338 protein-altering or splice-affecting, 139 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 293, Silent 139, Nonsense Mutation 30, Intron 5, In Frame Del 4, Frame Shift Ins 3, Splice Region 3, Splice Site 3, RNA 2, Nonstop Mutation 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRAF3IP1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886037898, CM1514989, COSV100966931; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.3296T>C p.L1099P | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99566110; called by muse, mutect2, varscan2
- ABCC11 | c.3664C>T p.P1222S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100750897; called by muse, mutect2, varscan2
- ABCC4 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV100972578; called by muse, mutect2, varscan2
- ABHD11 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as COSV99766861; called by muse, mutect2, varscan2
- ACSM2B | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61659846; called by muse, mutect2, varscan2
- ACTC1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV99291941; called by muse, mutect2, varscan2
- ADAM28 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1410573710, COSV99739077; called by muse, mutect2, varscan2
- ADAMTS20 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs773996468, COSV101239019, COSV67130583; called by muse, mutect2, varscan2
- ADAMTS3 | c.3604A>G p.T1202A | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV54386568; called by muse, mutect2, varscan2
- ADAMTS4 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs1435009764, COSV100917492; called by muse, mutect2, varscan2
- ADH1A | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.489); catalogued as COSV52926281; called by muse, mutect2, varscan2
- AIPL1 | c.500G>A p.W167* | Nonsense Mutation (SNP) | VAF 76/168 reads (45%) | catalogued as COSV100006108; called by muse, mutect2, varscan2
- ANAPC1 | c.5308C>T p.L1770F | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV61974308, COSV61978513; called by muse, mutect2, varscan2
- ANKS1A | c.3029C>T p.S1010F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64464301; called by muse, mutect2, varscan2
- ANO4 | c.2840G>A p.G947E (on ENST00000392977 / NM_001286615.2; = p.G912E on NM_178826.4) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); catalogued as COSV100153120; called by muse, mutect2
- ARHGEF15 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs775334628, COSV62725623; called by muse, mutect2, varscan2
- ARID1A | c.6229C>T p.P2077S | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV100251252; called by muse, mutect2, varscan2
- ARRDC5 | c.526G>A p.E176K (on ENST00000381781; = p.E162K on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745734884, COSV101108202; called by muse, mutect2, varscan2
- ASNSD1 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as COSV99641252; called by muse, mutect2, varscan2
- ASTN1 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99922218; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 394/692 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ATP13A5 | c.2597C>T p.S866L | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs866256714, COSV60868133; called by muse, mutect2, varscan2
- ATP1A3 | c.2859G>A p.K953= (on ENST00000545399 / NM_001256214.2; = p.K940= on NM_152296.5) | Splice Region (SNP) | VAF 9/14 reads (64%) | catalogued as COSV100132338; called by muse, mutect2, varscan2
- ATP2A3 | c.2387A>G p.N796S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99989363; called by muse, mutect2, varscan2
- ATP8B2 | c.2075C>T p.T692I (on ENST00000672630; = p.T659I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100528073; called by muse, mutect2, varscan2
- BAZ1B | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100289872; called by muse, mutect2, varscan2
- BCAN | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV100228223; called by muse, mutect2, varscan2
- BCLAF1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs374838456, COSV62143031; called by muse, mutect2, varscan2
- BRDT | c.2608G>A p.G870R | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1438596439, COSV100746456; called by muse, mutect2, varscan2
- BTBD8 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1391484558, COSV100730343; called by muse, mutect2, varscan2
- C12orf50 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100072310; called by muse, mutect2, varscan2
- C5AR2 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as rs1450713449, COSV99953796; called by muse, mutect2, varscan2
- C6 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54704604; called by muse, mutect2, varscan2
- C7 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167742526, COSV100496043; called by muse, mutect2, varscan2
- CACNA1C | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100219673; called by muse, mutect2, varscan2
- CALB2 | c.727T>A p.Y243N | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100226270; called by muse, mutect2, varscan2
- CALCOCO1 | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100017381; called by muse, mutect2, varscan2
- CAMK4 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99999664; called by muse, mutect2, varscan2
- CAMKV | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99615665; called by muse, mutect2, varscan2
- CAPN12 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.991); catalogued as COSV100185351; called by muse, mutect2
- CAPSL | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV68437095; called by muse, mutect2
- CATSPER2 | c.1367A>T p.E456V (on ENST00000321596 / NM_001282309.3; = p.E458V on NM_172095.4) | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV100390818; called by muse, mutect2, varscan2
- CATSPER2 | c.1366G>A p.E456K (on ENST00000321596 / NM_001282309.3; = p.E458K on NM_172095.4) | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.037); catalogued as COSV58660808; called by muse, mutect2, varscan2
- CAVIN1 | c.245T>A p.M82K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100824562; called by muse, mutect2, varscan2
- CAVIN2 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.006); catalogued as rs779917381, COSV58423788; called by muse, mutect2, varscan2
- CCDC30 | c.1469C>T p.A490V (on ENST00000340612; = p.A447V on NM_001080850.3) | Missense Mutation (SNP) | VAF 123/251 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV100501437; called by muse, mutect2, varscan2
- CCDC88B | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV100105578; called by muse, mutect2, varscan2
- CDHR1 | c.2110G>A p.V704M | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.076); catalogued as COSV100259065; called by muse, mutect2, varscan2
- CDSN | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV99456950; called by muse, mutect2, varscan2
- CDYL2 | c.1509T>G p.I503M | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV101629518; called by muse, mutect2
- CELSR2 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as COSV54777465; called by muse, mutect2, varscan2
- CEP126 | c.2939A>T p.K980M | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99681164; called by muse, mutect2
- CEP152 | c.2224A>T p.N742Y | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV100358924; called by muse, mutect2, varscan2
- CHD7 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV101418306; called by muse, mutect2, varscan2
- CHD7 | c.7441C>T p.Q2481* | Nonsense Mutation (SNP) | VAF 51/105 reads (49%) | catalogued as CM126642, COSV101418307, COSV71114198; called by muse, mutect2, varscan2
- CHIA | c.1271C>T p.S424L (on ENST00000343320; = p.S316L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs754393219, COSV58475780; called by muse, mutect2, varscan2
- CHPF | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99704991; called by muse, mutect2, varscan2
- CHRD | c.700-1G>A p.X234_splice | Splice Site (SNP) | VAF 90/237 reads (38%) | catalogued as COSV99200510; called by muse, mutect2, varscan2
- CHRNB4 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs779741330, COSV55716096; called by muse, mutect2, varscan2
- CLC | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55686103; called by muse, mutect2, varscan2
- CLCN6 | c.172A>T p.N58Y | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100412016; called by muse, mutect2, varscan2
- CLEC16A | c.826A>G p.N276D | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101278229; called by muse, mutect2, varscan2
- CLN6 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99992652; called by muse, mutect2, varscan2
- CLN6 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1239104101, COSV99992654; called by muse, mutect2, varscan2
- CLU | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.299); catalogued as COSV100324341; called by muse, varscan2
- CNBD1 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs906110946, COSV101582251; called by muse, mutect2, varscan2
- COL21A1 | c.2508A>G p.I836M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1446728322, COSV99779164; called by muse, varscan2
- COL4A1 | c.4307C>T p.P1436L | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV101011280; called by muse, mutect2, varscan2
- COL8A2 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 14/20 reads (70%) | catalogued as rs1474036423, COSV100291255; called by muse, mutect2, varscan2
- CPN2 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs571844961, COSV60472431; called by muse, mutect2, varscan2
- CRB1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100959044; called by muse, mutect2, varscan2
- CREBBP | c.7135C>T p.Q2379* | Nonsense Mutation (SNP) | VAF 45/107 reads (42%) | catalogued as COSV99270626; called by muse, mutect2, varscan2
- CRNN | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs745638738, COSV99664203; called by muse, mutect2, varscan2
- CROT | c.1302-2A>T p.X434_splice | Splice Site (SNP) | VAF 53/181 reads (29%) | catalogued as rs1411303024, COSV100519566; called by muse, mutect2, varscan2
- CRYBB3 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763378955, COSV99309106; called by muse, mutect2, varscan2
- CSMD1 | c.4799C>T p.P1600L (on ENST00000520002; = p.P1599L on NM_033225.6) | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.985); catalogued as rs749059971, COSV100149964; called by muse, varscan2
- CSMD2 | c.8671A>C p.I2891L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs768343851, COSV99591769; called by muse, mutect2, varscan2
- CSNK1G2 | c.1000C>T p.L334= | Splice Region (SNP) | VAF 32/72 reads (44%) | catalogued as rs777627702, COSV99730030; called by muse, mutect2, varscan2
- CSPP1 | c.1492C>T p.P498S (on ENST00000676605; = p.P457S on NM_024790.6) | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs546837200, COSV99138856; called by muse, mutect2, varscan2
- CTRC | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs1393898711, COSV101036385; called by muse, mutect2, varscan2
- CYP2S1 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100027497; called by muse, mutect2, varscan2
- DDX18 | c.1826T>C p.V609A | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV54306058; called by muse, mutect2, varscan2
- DMXL2 | c.6431G>A p.R2144Q | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs377032691, COSV99196556; called by muse, mutect2, varscan2
- DNAH11 | c.9620C>T p.A3207V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV60943084, COSV60962685; called by muse, mutect2, varscan2
- DNAH5 | c.9667G>A p.E3223K | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV54216325; called by muse, mutect2, varscan2
- DNAH5 | c.6149C>T p.S2050F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs865859969, COSV54207857; called by muse, mutect2, varscan2
- DNAH5 | c.4781C>T p.S1594F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99451137; called by muse, mutect2, varscan2
- DNAJC5B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs141686243, COSV52535470; called by muse, mutect2, varscan2
- DNPEP | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV99815270; called by muse, mutect2, varscan2
- DPYD | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100928980; called by muse, mutect2, varscan2
- DSCAM | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as rs750290290, COSV68027085; called by muse, mutect2, varscan2
- EDNRA | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100163471; called by muse, mutect2
- ELOVL4 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100876328; called by muse, mutect2, varscan2
- EMCN | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as COSV99598472; called by muse, mutect2, varscan2
- ERC1 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100706213; called by muse, mutect2, varscan2
- ERCC2 | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99676371; called by muse, mutect2, varscan2
- ETS2 | c.1209G>C p.W403C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100711311; called by muse, mutect2
- EXOC6 | c.1750C>T p.L584F | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99592112; called by muse, mutect2, varscan2
- FARP1 | c.2468A>G p.H823R | Missense Mutation (SNP) | VAF 123/275 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1418904115, COSV60347094; called by muse, mutect2, varscan2
- FDXR | c.995G>A p.R332K (on ENST00000293195 / NM_024417.5; = p.R338K on NM_004110.6) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99501145; called by muse, mutect2, varscan2
- FER1L6 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV101205974; called by muse, mutect2, varscan2
- FFAR2 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.557); catalogued as rs368220138; called by muse, mutect2, varscan2
- FGD5 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53244396; called by muse, mutect2, varscan2
- FLG | c.6188G>A p.G2063E | Missense Mutation (SNP) | VAF 177/518 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs867944258, COSV100911693; called by muse, mutect2, varscan2
- FLG | c.760A>T p.N254Y | Missense Mutation (SNP) | VAF 125/237 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100911694; called by muse, mutect2, varscan2
- FLNC | c.5509G>A p.G1837R | Missense Mutation (SNP) | VAF 112/197 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.158); catalogued as COSV100368308; called by muse, mutect2, varscan2
- GABRA1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99196010; called by muse, mutect2, varscan2
- GABRA4 | c.516T>G p.C172W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99974234; called by muse, varscan2
- GCSAML | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100825879, COSV63579149; called by muse, mutect2, varscan2
- GDF3 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs866471146, COSV61712086; called by muse, mutect2, varscan2
- GK | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 43/52 reads (83%) | catalogued as COSV66738591; called by muse, mutect2, varscan2
- GLP1R | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100952634; called by muse, mutect2, varscan2
- GPATCH8 | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs199963233, COSV59199586; called by muse, mutect2, varscan2
- GRM7 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 47/84 reads (56%) | catalogued as rs267599933, COSV63130808; called by muse, mutect2, varscan2
- GRM8 | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100283919; called by muse, mutect2, varscan2
- GUCY2C | c.928T>A p.F310I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs1199236083, COSV99663787; called by muse, mutect2, varscan2
- HMGB2 | c.396G>T p.M132I | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99632749; called by muse, mutect2, varscan2
- HOXB5 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99494600; called by muse, mutect2, varscan2
- HOXB5 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99494605; called by muse, mutect2, varscan2
- HOXD4 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.77); catalogued as COSV100106910, COSV60460270; called by muse, mutect2
- HS3ST4 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.895); catalogued as rs1193961102, COSV100501737, COSV104403178; called by muse, mutect2, varscan2
- HSPA4L | c.2268C>A p.N756K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.13); catalogued as rs1280683878, COSV99613200; called by muse, mutect2, varscan2
- IFT52 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as COSV65974552; called by muse, mutect2, varscan2
- IGLV6-57 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); catalogued as rs192435787; called by muse, mutect2, varscan2
- IGSF1 | c.3442C>T p.H1148Y | Missense Mutation (SNP) | VAF 116/135 reads (86%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs267606354, COSV100812165; called by muse, mutect2, varscan2
- INSRR | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100947687; called by muse, mutect2, varscan2
- IQCH | c.232A>T p.N78Y | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV100245994; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1204125033, COSV99860871; called by muse, mutect2, varscan2
- ITIH5 | c.2207A>T p.K736I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99905026; called by muse, mutect2, varscan2
- ITIH5 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.953); catalogued as COSV99905028; called by muse, mutect2, varscan2
- ITK | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV101439805; called by muse, mutect2, varscan2
- KCNA1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.206); catalogued as rs747465523, COSV66836969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KHDC3L | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1254478088, COSV64862954; called by muse, mutect2, varscan2
- KIAA1841 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1418040986, COSV99693878, COSV99694328; called by muse, mutect2, varscan2
- KIRREL3 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73107286; called by muse, mutect2, varscan2
- KRTAP3-1 | c.183T>A p.Y61* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV101196084; called by muse, mutect2, varscan2
- L1TD1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.746); catalogued as COSV100776596; called by muse, mutect2, varscan2
- LAMA5 | c.5128G>A p.G1710R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1231635430, COSV99440736; called by muse, mutect2
- LANCL1 | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV99286347; called by muse, mutect2, varscan2
- LCP2 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99253001; called by muse, mutect2
- LDHB | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.746); catalogued as COSV100636425; called by muse, mutect2, varscan2
- LDLRAD4 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs758903290, COSV100762385; called by muse, mutect2, varscan2
- LGALS13 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.688); catalogued as COSV99694974; called by muse, mutect2, varscan2
- LGR6 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1227367165, COSV100938149; called by muse, mutect2, varscan2
- LILRB1 | c.1606C>T p.R536* (on ENST00000427581; = p.R486* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as rs754376189, COSV61116188; called by muse, mutect2, varscan2
- LMOD1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100939197; called by muse, mutect2, varscan2
- LPP | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779323597, COSV57112662; called by muse, mutect2, varscan2
- LUM | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 117/190 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV99899092; called by muse, mutect2, varscan2
- MACF1 | c.1804A>G p.K602E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100485138; called by muse, mutect2, varscan2
- MAGEC1 | c.3226C>T p.H1076Y | Missense Mutation (SNP) | VAF 102/115 reads (89%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); catalogued as COSV53570272; called by muse, mutect2, varscan2
- MAP1B | c.3928T>C p.C1310R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV99702578; called by muse, mutect2, varscan2
- MAP3K21 | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 88/132 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as COSV100786119, COSV100786160; called by muse, mutect2, varscan2
- MBD5 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101290136; called by muse, mutect2, varscan2
- MBD5 | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV68696223; called by muse, mutect2, varscan2
- MBD5 | c.2990G>T p.G997V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101290138; called by muse, mutect2, varscan2
- MCTP2 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59146570; called by muse, mutect2, varscan2
- MICALL1 | c.2198A>G p.H733R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99317374; called by muse, mutect2, varscan2
- MMP10 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010329318, COSV99666613; called by muse, mutect2, varscan2
- MMP10 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1217547809, COSV99666614; called by muse, mutect2, varscan2
- MORC1 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 52/56 reads (93%) | catalogued as rs1458516252, COSV51714819; called by muse, mutect2, varscan2
- MPPED2 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs745317470, COSV63896832; called by muse, mutect2, varscan2
- MRC2 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs765509790, COSV57640857; called by muse, mutect2, varscan2
- MS4A8 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100282569; called by muse, mutect2, varscan2
- MSR1 | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100027513; called by muse, mutect2, varscan2
- MTBP | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.935); catalogued as rs1456591244, COSV100012277; called by muse, mutect2, varscan2
- MTOR | c.7247C>T p.A2416V | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173643064, COSV63868538, COSV63873144; called by muse, mutect2, varscan2
- MUC16 | c.39334G>A p.E13112K | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV101109950; called by muse, mutect2, varscan2
- MUC16 | c.7888C>T p.P2630S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67476439; called by muse, varscan2
- MYCBP2 | c.8323C>G p.P2775A (on ENST00000357337; = p.P2813A on NM_015057.5) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV100630766; called by muse, mutect2, varscan2
- MYH4 | c.2680C>T p.Q894* | Nonsense Mutation (SNP) | VAF 78/200 reads (39%) | catalogued as COSV99701585; called by muse, mutect2, varscan2
- MYH7 | c.2002C>T p.H668Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM137782, COSV100806253; called by muse, mutect2, varscan2
- MYNN | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs369446786, COSV100582160; called by muse, mutect2, varscan2
- NAAA | c.962T>G p.L321R | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99715971; called by muse, mutect2, varscan2
- NAAA | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV99715974; called by muse, mutect2, varscan2
- NAGLU | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV99864222; called by muse, mutect2, varscan2
- NLGN4Y | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99946104; called by muse, mutect2, varscan2
- NLRC4 | c.1751T>C p.L584S | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100707433; called by muse, mutect2, varscan2
- NLRP12 | c.2507G>A p.G836E | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as COSV100144968, COSV60743784; called by muse, mutect2
- NOTCH3 | c.6107C>T p.P2036L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs1428027646, COSV54639269; called by muse, mutect2
- NOTCH4 | c.3539G>A p.G1180D | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.898); catalogued as COSV100900759; called by muse, mutect2, varscan2
- NPAS2 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as rs1253534857, COSV100176424; called by muse, mutect2, varscan2
- NRF1 | c.1496T>G p.V499G | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV56217279, COSV99781901; called by muse, mutect2, varscan2
- NRK | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs1350391117, COSV54588712, COSV99688277; called by muse, mutect2, varscan2
- NRXN1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as rs1354401829, COSV101277724; called by muse, mutect2, varscan2
- NT5DC1 | c.141C>A p.Y47* | Nonsense Mutation (SNP) | VAF 40/55 reads (73%) | catalogued as COSV100126887, COSV60310736; called by muse, mutect2, varscan2
- NTRK3 | c.1974C>A p.H658Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.261); catalogued as COSV100713074; called by mutect2, varscan2
- NUDT7 | c.592T>G p.L198V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV99216111; called by muse, mutect2, varscan2
- NUP107 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 90/127 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1331880195, COSV99971850; called by muse, mutect2, varscan2
- NYNRIN | c.5116C>T p.R1706W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs762480375, COSV101230629; called by muse, varscan2
- OR13C3 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV101053331; called by muse, mutect2, varscan2
- OR3A2 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV101375060, COSV68695188; called by muse, mutect2, varscan2
- OR4C12 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); catalogued as COSV58861093; called by muse, mutect2, varscan2
- OR52K1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56904585; called by muse, mutect2, varscan2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OR6C6 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100626492; called by muse, mutect2, varscan2
- OR8B12 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV60913044; called by muse, mutect2, varscan2
- OSBPL7 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99136577; called by muse, mutect2, varscan2
- OSCP1 | c.589C>T p.R197C (on ENST00000356637 / NM_001330493.1; = p.R187C on NM_145047.5) | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs149060854; called by muse, mutect2
- OTUD3 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs191701178, COSV100909030; called by muse, mutect2, varscan2
- OTUD4 | c.2924T>C p.V975A (on ENST00000447906 / NM_001366057.1; = p.V910A on NM_001102653.1) | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101486007; called by muse, mutect2, varscan2
- PAPPA | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT tolerated (0.84); PolyPhen benign (0.11); catalogued as COSV100074495; called by muse, varscan2
- PARD3B | c.1672C>G p.L558V | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100594024, COSV62505556; called by muse, mutect2, varscan2
- PCDH15 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100222809; called by muse, mutect2, varscan2
- PCDHGA7 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99541156; called by muse, mutect2
- PCDHGB2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463247472, COSV99541154, COSV99543577; called by muse, mutect2, varscan2
- PCLO | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.012); catalogued as rs747593233, COSV61667530; called by muse, mutect2
- PCYT2 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.516); catalogued as COSV100155602; called by muse, mutect2, varscan2
- PDE1C | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs1428705886, COSV101275550; called by muse, mutect2, varscan2
- PDZK1 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100572477; called by muse, mutect2, varscan2
- PHACTR1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100277567; called by muse, mutect2, varscan2
- PHLDB3 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV52667564; called by muse, mutect2
- PIK3C3 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.323); catalogued as COSV100011136; called by muse, mutect2, varscan2
- PIK3CG | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.779); catalogued as COSV100783339, COSV63246881; called by muse, mutect2, varscan2
- PKD1L1 | c.7093G>A p.G2365R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.286); catalogued as COSV99220291; called by muse, mutect2, varscan2
- PLCL2 | c.1225C>T p.L409F (on ENST00000615277 / NM_001144382.2; = p.L283F on NM_015184.5) | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101196819; called by muse, mutect2, varscan2
- PLXNA1 | c.4771C>T p.Q1591* | Nonsense Mutation (SNP) | VAF 11/15 reads (73%) | catalogued as COSV99303421; called by muse, mutect2
- PNPLA7 | c.3191C>T p.S1064F | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289987078, COSV99480986; called by muse, mutect2, varscan2
- POLQ | c.7151A>G p.Q2384R | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99952448; called by muse, mutect2, varscan2
- POSTN | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV101123388; called by muse, mutect2, varscan2
- POTEF | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); catalogued as rs769535061, COSV100665043; called by muse, mutect2, varscan2
- PPFIA3 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1385824260, COSV61950900, COSV61951594; called by muse, mutect2
- PPP1R9A | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56915750; called by muse, mutect2, varscan2
- PPP2R5B | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51211008, COSV99376240; called by muse, mutect2, varscan2
- PRKG2 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 45/123 reads (37%) | catalogued as COSV100020054; called by muse, mutect2, varscan2
- PRPF39 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1240102889, COSV63276817; called by muse, mutect2, varscan2
- PRRC2C | c.4268G>A p.R1423Q (on ENST00000367742; = p.R1421Q on NM_015172.4) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs1395509443, COSV100145481; called by muse, mutect2, varscan2
- PSG5 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 129/255 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100742893; called by muse, mutect2, varscan2
- PTK7 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.371); catalogued as rs1221719721, COSV100030271; called by muse, mutect2, varscan2
- PTPRB | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs184275696, COSV54232350, COSV99715331; called by muse, mutect2, varscan2
- RABEP1 | c.1997A>G p.E666G | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99336752; called by muse, mutect2, varscan2
- RET | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100393599, COSV100393914; called by muse, mutect2, varscan2
- RFPL2 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.502); catalogued as rs770071733, COSV50716765, COSV99964177; called by muse, mutect2, varscan2
- RIN1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1219446140, COSV100254751, COSV60926821; called by muse, mutect2, varscan2
- RNF139 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1563628536, COSV100337884; called by muse, mutect2, varscan2
- RNF157 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV99487125; called by muse, mutect2, varscan2
- RNF25 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99829082; called by muse, mutect2, varscan2
- ROCK1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101296467; called by muse, mutect2, varscan2
- ROCK1 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101296468; called by muse, mutect2, varscan2
- RPS9 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as rs1346531635, COSV100256438; called by muse, mutect2, varscan2
- RTL4 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 112/142 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs747112680, COSV100466027; called by muse, mutect2, varscan2
- RYR1 | c.12271G>A p.D4091N | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62088260; called by muse, mutect2, varscan2
- RYR2 | c.6314C>T p.T2105I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100771319; called by muse, mutect2, varscan2
- SALL1 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51766056, COSV99174546; called by muse, mutect2, varscan2
- SALL1 | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs768379347, COSV51755097; called by muse, mutect2, varscan2
- SAMSN1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.093); catalogued as rs760968832, COSV53469749; called by muse, mutect2, varscan2
- SART3 | c.2305G>C p.V769L (on ENST00000228284; = p.V751L on NM_014706.4) | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as COSV99934178; called by muse, mutect2, varscan2
- SCARA3 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs150039603; called by muse, mutect2, varscan2
- SCLY | c.1193C>T p.S398L (on ENST00000651534; = p.S390L on NM_016510.7) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs369781333, COSV99615487; called by muse, mutect2, varscan2
- SCN11A | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571721216, COSV56565730; called by muse, mutect2, varscan2
- SCN9A | c.5563G>A p.E1855K (on ENST00000303354; = p.E1844K on NM_002977.3) | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs876661248, COSV100313322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC14L3 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as rs768564832, COSV99307207; called by muse, mutect2, varscan2
- SEC63 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 50/62 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100938423; called by muse, mutect2, varscan2
- SELE | c.73A>C p.N25H | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV100324900; called by muse, mutect2, varscan2
- SELL | c.923T>G p.L308* (on ENST00000650983; = p.L295* on NM_000655.5) | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99357643; called by muse, mutect2, varscan2
- SERPINB10 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as rs1436124033, COSV99449372; called by muse, mutect2, varscan2
- SEZ6L | c.2265G>A p.W755* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as COSV99962358; called by muse, mutect2, varscan2
- SH3GL3 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100196973; called by muse, mutect2, varscan2
- SH3RF2 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100767844; called by muse, mutect2, varscan2
- SI | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865867843, COSV100016091, COSV52271812; called by muse, mutect2
- SIGLEC7 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV58317603; called by muse, mutect2, varscan2
- SIM1 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.142); catalogued as COSV53492605; called by muse, mutect2, varscan2
- SLC12A9 | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 107/186 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99307935; called by muse, mutect2, varscan2
- SLC41A3 | c.273G>A p.Q91= | Splice Region (SNP) | VAF 47/58 reads (81%) | catalogued as COSV100259672, COSV59988983; called by muse, mutect2, varscan2
- SLC4A8 | c.2743G>A p.G915R | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177103; called by muse, mutect2, varscan2
- SLC6A5 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100116990; called by muse, mutect2, varscan2
- SLC8A3 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63523816; called by muse, mutect2, varscan2
- SMG6 | c.3913G>T p.E1305* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99558378; called by muse, mutect2, varscan2
- SMOC1 | c.1303T>A p.*435Kext*36 | Nonstop Mutation (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100734676; called by muse, mutect2
- SMOC1 | c.1305A>C p.*435Yext*36 | Nonstop Mutation (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100734677; called by muse, mutect2
- SNCAIP | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54408480, COSV99749284; called by muse, mutect2, varscan2
- SPEG | c.5824G>T p.E1942* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV56683889; called by muse, mutect2, varscan2
- SPINK5 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.2); catalogued as COSV99806937; called by muse, mutect2, varscan2
- SPNS2 | c.1327A>C p.T443P | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100223706; called by muse, mutect2, varscan2
- SPPL2C | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV100234081; called by muse, mutect2, varscan2
- SPTBN4 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); catalogued as COSV58947506; called by muse, mutect2, varscan2
- SRRM4 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.99); catalogued as COSV99938772; called by muse, mutect2, varscan2
- SSUH2 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100435920; called by muse, mutect2, varscan2
- ST18 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs759213511, COSV99390092; called by muse, mutect2, varscan2
- ST8SIA2 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 35/78 reads (45%) | PolyPhen probably damaging (1); catalogued as COSV51569326; called by muse, mutect2, varscan2
- STAC2 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.355); catalogued as rs1231104405, COSV100336421; called by muse, mutect2, varscan2
- STK33 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV59396548, COSV59401196; called by muse, mutect2, varscan2
- SULF1 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs1563576026, COSV52676256; called by muse, mutect2, varscan2
- SUPT6H | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1346511271, COSV100112533; called by muse, mutect2, varscan2
- SUSD4 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as rs768968054, COSV100663812; called by muse, mutect2, varscan2
- SYNE1 | c.18817G>A p.E6273K (on ENST00000367255 / NM_182961.4; = p.E6202K on NM_033071.3) | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs201346604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT1 | c.1148G>A p.S383N | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99696062; called by muse, mutect2, varscan2
- SYT4 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.086); catalogued as COSV99674004; called by muse, mutect2, varscan2
- TACR3 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100510608; called by muse, mutect2, varscan2
- TBC1D8B | c.2812+1G>A p.X938_splice | Splice Site (SNP) | VAF 25/33 reads (76%) | catalogued as rs1331717043, COSV99344591; called by muse, mutect2, varscan2
- TBC1D9 | c.564T>G p.F188L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101464365; called by muse, mutect2, varscan2
- TEX11 | c.1356G>A p.M452I (on ENST00000344304; = p.M437I on NM_031276.3) | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100721924; called by muse, mutect2, varscan2
- THSD7B | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs373017033; called by muse, mutect2, varscan2
- TIGD3 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.144); catalogued as rs1291506910, COSV52888243; called by muse, mutect2, varscan2
- TMED9 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs866118614, COSV99219066; called by muse, mutect2, varscan2
- TMEM163 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99926569; called by muse, mutect2, varscan2
- TMEM174 | c.209G>A p.W70* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV57113141; called by muse, mutect2, varscan2
- TMEM270 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 449/767 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as rs1240770909, COSV100260368; called by muse, mutect2, varscan2
- TNRC18 | c.3318C>G p.D1106E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs750118272, COSV101269726, COSV68169392, COSV68171659; called by muse, mutect2, varscan2
- TRANK1 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.176); catalogued as COSV100083483; called by muse, mutect2
- TRAPPC11 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100591910; called by muse, mutect2, varscan2
- TRAV6 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs1213744651; called by muse, mutect2, varscan2
- TRIB3 | c.877C>A p.R293S | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV99423851; called by muse, mutect2, varscan2
- TRIO | c.7778G>C p.R2593P | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100702636; called by muse, mutect2, varscan2
- TTN | c.97226T>G p.V32409G (on ENST00000591111; = p.V24985G on NM_003319.4) | Missense Mutation (SNP) | VAF 9/126 reads (7%) | PolyPhen possibly damaging (0.771); catalogued as COSV100618767; called by muse, mutect2
- TTN | c.31181G>A p.R10394K (on ENST00000591111; = p.R9467K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | PolyPhen benign (0); catalogued as COSV60216044; called by muse, mutect2, varscan2
- TTN | c.14652G>A p.W4884* (on ENST00000591111; = p.W3957* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/146 reads (38%) | catalogued as COSV100588743; called by muse, mutect2, varscan2
- TTN | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | PolyPhen probably damaging (0.947); catalogued as rs372632047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100013391; called by muse, mutect2, varscan2
- UBAP2L | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs1476819045, COSV55171185; called by muse, mutect2, varscan2
- UPP2 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV99135047; called by muse, mutect2, varscan2
- USP5 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV57532303, COSV99977417; called by muse, mutect2, varscan2
- USP53 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56793567; called by muse, mutect2, varscan2
- USP6NL | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.162); catalogued as rs1237113764, COSV99509798; called by muse, mutect2, varscan2
- VSTM1 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100618822; called by muse, mutect2, varscan2
- VSTM4 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53676936, COSV53678357; called by muse, mutect2, varscan2
- WBP4 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101069291; called by muse, mutect2, varscan2
- ZBED9 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV71729208; called by muse, mutect2, varscan2
- ZFHX4 | c.8162G>A p.G2721E | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs756937981, COSV99264307; called by muse, mutect2, varscan2
- ZFP36L2 | c.431dup p.G145Rfs*329 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | catalogued as rs1558428769; called by mutect2, pindel, varscan2
- ZNF131 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1561436858, COSV100185552; called by muse, mutect2, varscan2
- ZNF334 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 176/278 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs769146818, COSV61619033; called by muse, mutect2, varscan2
- ZNF532 | c.3596A>G p.D1199G | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1239551709, COSV100266764; called by muse, mutect2, varscan2
- ZNF540 | c.439A>T p.K147* | Nonsense Mutation (SNP) | VAF 54/90 reads (60%) | catalogued as COSV100329754, COSV57108094; called by muse, mutect2, varscan2
- ZNF560 | c.533G>A p.W178* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as rs1471622977, COSV100038209; called by muse, mutect2, varscan2
- ZNF585A | c.622C>T p.H208Y (on ENST00000292841 / NM_001288800.2; = p.H153Y on NM_152655.3) | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53061761; called by muse, mutect2, varscan2
- ZNF699 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 43/106 reads (41%) | catalogued as COSV100426986; called by muse, mutect2, varscan2
- ZNF710 | c.756T>G p.S252R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1378605906, COSV99184186; called by muse, mutect2, varscan2
- ZNF804A | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV56449169; called by muse, mutect2, varscan2
- ZSWIM2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs780115062, COSV54573844; called by muse, mutect2, varscan2
- BRAF | c.1577_1591del p.N526_P530del (on ENST00000288602 / NM_001374244.1; = p.N486_P490del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 34/93 reads (37%) | called by mutect2, pindel, varscan2
- BRD2 | c.1656dup p.E553Rfs*19 | Frame Shift Ins (INS) | VAF 20/107 reads (19%) | called by mutect2, pindel, varscan2
- CARMIL2 | c.1972_1989del p.A658_Q663del | In Frame Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- HSPE1-MOB4 | c.12_41del p.Q4_D14delinsH | In Frame Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- MYO5A | c.4676_4687del p.S1559_R1563delins* | Nonsense Mutation (DEL) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- TPTE | c.961G>A p.E321K (on ENST00000618007 / NM_199261.4; = p.E303K on NM_199259.4) | Missense Mutation (SNP) | VAF 71/359 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1721_1738del p.R574_M579del | In Frame Del (DEL) | VAF 18/78 reads (23%) | called by mutect2, pindel
- VIRMA | c.2407dup p.T803Nfs*3 | Frame Shift Ins (INS) | VAF 48/109 reads (44%) | called by mutect2, pindel, varscan2
- A2M | c.315C>T p.V105= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100588779; called by muse, mutect2, varscan2
- ACSL6 | c.2043G>A p.L681= (on ENST00000379240; = p.L706= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV99734059; called by muse, mutect2, varscan2
- ACTR5 | c.918G>A p.Q306= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV99710088; called by muse, mutect2, varscan2
- ADAMTS16 | c.480C>T p.A160= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV99941731; called by muse, mutect2, varscan2
- ADCY7 | c.1257C>T p.A419= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99576133; called by muse, mutect2
- ADK | c.834C>T p.I278= (on ENST00000286621; = p.I261= on NM_001123.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs773469754, COSV54215388; called by muse, mutect2, varscan2
- AFF2 | c.1881G>A p.G627= | Silent (SNP) | VAF 69/81 reads (85%) | catalogued as rs868938185, COSV53983439; called by muse, mutect2, varscan2
- AKR1D1 | c.801G>A p.G267= | Silent (SNP) | VAF 93/162 reads (57%) | catalogued as rs774563507, COSV99653147; called by muse, mutect2, varscan2
- ANK3 | c.10401C>T p.I3467= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as rs200592890, COSV55058289; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARSL | c.663C>T p.P221= | Silent (SNP) | VAF 20/22 reads (91%) | catalogued as COSV101140629; called by muse, mutect2, varscan2
- ATP10B | c.447C>T p.C149= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs1172803561, COSV100469397, COSV100469514; called by muse, mutect2, varscan2
- ATP12A | c.375C>T p.L125= | Silent (SNP) | VAF 117/318 reads (37%) | catalogued as rs544490511, COSV54514162, COSV99517912; called by muse, mutect2, varscan2
- ATP6V1F | c.108C>T p.F36= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV99925983; called by muse, mutect2, varscan2
- AZGP1 | c.633C>T p.V211= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99448017; called by muse, mutect2, varscan2
- BACH2 | c.921C>T p.V307= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as rs779277240, COSV57601931; called by muse, mutect2, varscan2
- BCO2 | c.1645C>T p.L549= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs753077095, COSV100730392; called by muse, mutect2, varscan2
- BOD1L1 | c.7491G>A p.G2497= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99239716; called by muse, mutect2, varscan2
- BRPF1 | c.681C>T p.I227= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV100121302; called by muse, mutect2, varscan2
- BTBD6 | c.913C>T p.L305= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs752312583, COSV100527448, COSV59265602; called by muse, mutect2, varscan2
- C12orf4 | c.219C>T p.S73= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as COSV54209327, COSV99712801; called by muse, mutect2, varscan2
- C5AR2 | c.204G>A p.V68= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99953795; called by muse, mutect2, varscan2
- CCDC150 | c.1110C>T p.I370= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1378729397, COSV99777094; called by muse, mutect2, varscan2
- CDC42BPA | c.3108A>G p.L1036= (on ENST00000334218 / NM_001366019.2; = p.L1023= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100505821; called by muse, mutect2, varscan2
- CDRT1 | c.718C>T p.L240= | Silent (SNP) | VAF 77/211 reads (36%) | catalogued as COSV99887579; called by muse, mutect2, varscan2
- CELSR2 | c.1257C>T p.L419= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV54777265, COSV99604147; called by muse, mutect2, varscan2
- CENPE | c.6753C>T p.F2251= | Silent (SNP) | VAF 75/181 reads (41%) | catalogued as COSV99478316; called by muse, mutect2, varscan2
- CHAT | c.1335C>T p.F445= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs752229820, COSV60321555; called by muse, mutect2, varscan2
- CHPF | c.1356C>T p.Y452= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99705070; called by muse, mutect2, varscan2
- CLDN23 | c.321C>T p.D107= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1288622214, COSV101093131; called by muse, mutect2, varscan2
- CSMD3 | c.3738G>A p.T1246= (on ENST00000297405 / NM_001363185.1; = p.T1142= on NM_052900.3) | Silent (SNP) | VAF 75/141 reads (53%) | catalogued as rs1395803496, COSV52117937, COSV52310072; ClinVar: likely benign; called by muse, mutect2, varscan2
- DIAPH3 | c.1854C>T p.F618= (on ENST00000400324 / NM_001042517.2; = p.F355= on NM_030932.3) | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV57380851; called by muse, mutect2, varscan2
- DNAH11 | c.9621C>T p.A3207= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100179632; called by muse, mutect2, varscan2
- DNAH2 | c.6498C>T p.F2166= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs576012683, COSV66717116; called by muse, mutect2, varscan2
- DNPEP | c.144C>T p.C48= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV99815276; called by muse, mutect2, varscan2
- EDRF1 | c.3501C>T p.L1167= (on ENST00000356792 / NM_001202438.2; = p.L1133= on NM_015608.2) | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV100523614; called by muse, mutect2, varscan2
- EIF4G2 | c.2022C>T p.F674= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV101150935; called by muse, mutect2, varscan2
- EIF5AL1 | c.120C>T p.I40= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs1279546530, COSV101592807; called by muse, mutect2, varscan2
- ELFN2 | c.1743C>T p.L581= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV101297574; called by muse, mutect2, varscan2
- EMILIN2 | c.2067G>A p.K689= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV99598638; called by muse, mutect2, varscan2
- EPB41L4A | c.1971A>G p.K657= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs1384568393, COSV99813609; called by muse, mutect2, varscan2
- EPPIN | c.351C>T p.F117= | Silent (SNP) | VAF 125/166 reads (75%) | catalogued as COSV60548523; called by muse, mutect2, varscan2
- F8 | c.5136G>A p.K1712= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as rs782740320, COSV100811638, COSV64269603; called by muse, mutect2, varscan2
- FAM170A | c.471G>A p.R157= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as COSV100089114; called by muse, mutect2, varscan2
- FAM83F | c.1299C>T p.A433= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100329001; called by muse, mutect2, varscan2
- FARS2 | c.429C>T p.N143= | Silent (SNP) | VAF 61/92 reads (66%) | catalogued as COSV99212875, COSV99213062; called by muse, mutect2, varscan2
- FTMT | c.129C>T p.I43= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs554430526, COSV100360377; called by muse, varscan2
- GJD2 | c.747G>A p.E249= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV51747294, COSV99290692; called by muse, mutect2, varscan2
- GRIA2 | c.1434G>A p.T478= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs745408425, COSV52391837; called by muse, mutect2, varscan2
- HAVCR1 | c.387C>T p.V129= | Silent (SNP) | VAF 66/245 reads (27%) | catalogued as COSV59403502; called by muse, mutect2, varscan2
- HELLS | c.1650C>T p.I550= | Silent (SNP) | VAF 65/145 reads (45%) | catalogued as COSV99492183; called by muse, mutect2, varscan2
- HS3ST4 | c.1056C>T p.I352= | Silent (SNP) | VAF 59/136 reads (43%) | catalogued as rs763501744, COSV100501904; called by muse, mutect2, varscan2
- HTR2C | c.789C>T p.F263= | Silent (SNP) | VAF 109/130 reads (84%) | catalogued as COSV52204815; called by muse, mutect2, varscan2
- IL18R1 | c.1302G>A p.E434= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV52124135; called by muse, mutect2, varscan2
- ITGAD | c.3120C>T p.F1040= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV99791421; called by muse, mutect2, varscan2
- ITIH2 | c.2499G>A p.K833= | Silent (SNP) | VAF 46/83 reads (55%) | catalogued as COSV64435701; called by muse, mutect2, varscan2
- KIF16B | c.3297C>T p.S1099= | Silent (SNP) | VAF 63/82 reads (77%) | catalogued as rs1274028189, COSV100734512, COSV100734789; called by muse, mutect2, varscan2
- KIF27 | c.3033G>A p.E1011= | Silent (SNP) | VAF 167/196 reads (85%) | catalogued as COSV52831865; called by muse, mutect2, varscan2
- LAMB3 | c.2145C>T p.F715= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV61915478; called by muse, mutect2, varscan2
- LMNA | c.1534C>T p.L512= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100738747; called by muse, mutect2
- LRFN5 | c.1131C>T p.L377= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99984415, COSV99984526; called by muse, mutect2, varscan2
- MAP4K4 | c.1068C>T p.F356= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100155201; called by muse, mutect2, varscan2
- MARCHF10 | c.345G>A p.R115= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100248302; called by muse, mutect2, varscan2
- MKRN3 | c.768G>A p.E256= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs775427122, COSV100091324; called by muse, mutect2, varscan2
- MN1 | c.2757C>T p.S919= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100179919; called by muse, mutect2, varscan2
- MUC16 | c.9135C>T p.P3045= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV101200310; called by muse, mutect2, varscan2
- MUC16 | c.7926T>A p.T2642= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV101200311, COSV67459947; called by muse, varscan2
- MUC6 | c.1083C>T p.L361= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs1215058176, COSV101424653; called by muse, mutect2, varscan2
- MYO7B | c.495G>A p.T165= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs368886495, COSV101268098; called by muse, mutect2, varscan2
- NADK | c.951C>T p.I317= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs770339120, COSV100410577; called by muse, mutect2, varscan2
- NAGLU | c.2016C>T p.T672= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs1438567691, COSV99864223; called by muse, mutect2, varscan2
- NEIL3 | c.1368A>G p.E456= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV52811686; called by muse, mutect2
- OR2T4 | c.723C>T p.I241= | Silent (SNP) | VAF 240/357 reads (67%) | catalogued as COSV63543507; called by muse, mutect2, varscan2
- OR6A2 | c.30G>T p.V10= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100215639, COSV100215766; called by muse, mutect2, varscan2
- OR6K6 | c.96G>A p.G32= (on ENST00000368144; = p.G8= on NM_001005184.1) | Silent (SNP) | VAF 74/152 reads (49%) | catalogued as rs774355514, COSV63743967; called by muse, mutect2, varscan2
- OTOF | c.5568G>A p.R1856= (on ENST00000272371 / NM_194248.3; = p.R1089= on NM_004802.4) | Silent (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2
- PACSIN1 | c.1155C>T p.S385= | Silent (SNP) | VAF 127/228 reads (56%) | catalogued as COSV99762854; called by muse, mutect2, varscan2
- PARP4 | c.2524A>C p.R842= | Silent (SNP) | VAF 48/105 reads (46%) | catalogued as COSV101131743; called by muse, mutect2, varscan2
- PCDH15 | c.4632G>A p.Q1544= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as COSV57281879; called by muse, mutect2, varscan2
- PHLDB3 | c.1917C>T p.A639= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99415665; called by muse, mutect2
- PKNOX2 | c.468G>A p.K156= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as COSV100021144; called by muse, mutect2, varscan2
- PKP2 | c.1650C>T p.L550= | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as rs1320642436, COSV50731151; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEC | c.4116C>G p.A1372= (on ENST00000322810 / NM_201380.4; = p.A1262= on NM_000445.5) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100515670; called by muse, mutect2, varscan2
- PLXNA2 | c.5028C>T p.I1676= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as COSV100885596; called by muse, mutect2, varscan2
- PLXNB1 | c.3855C>T p.I1285= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99603028; called by muse, mutect2, varscan2
- POTEH | c.495C>T p.F165= | Silent (SNP) | VAF 45/287 reads (16%) | catalogued as rs749778428, COSV58882371; called by muse, mutect2, varscan2
- PPARGC1A | c.453A>G p.P151= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV99338132; called by muse, mutect2, varscan2
- PRAMEF14 | c.960T>G p.G320= | Silent (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- PRAMEF2 | c.1176C>T p.D392= | Silent (SNP) | VAF 26/214 reads (12%) | catalogued as rs199716299, COSV53573629; called by mutect2, varscan2
- PRAMEF7 | c.1272C>T p.L424= | Silent (SNP) | VAF 71/412 reads (17%) | catalogued as COSV100435114; called by muse, mutect2, varscan2
- PRPS1L1 | c.468G>A p.R156= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV72649978, COSV72649996; called by muse, mutect2, varscan2
- PTPRO | c.1023C>T p.F341= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs1223045742, COSV99840939; called by muse, mutect2, varscan2
- RAMP1 | c.99T>C p.G33= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV99614785; called by muse, mutect2, varscan2
- RASGRF1 | c.870C>T p.F290= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV101369673; called by muse, mutect2, varscan2
- RASSF1 | c.1002C>T p.I334= (on ENST00000357043 / NM_170714.2; = p.I330= on NM_007182.5) | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV99222777; called by muse, mutect2, varscan2
- RDH8 | c.294C>T p.S98= (on ENST00000651512; = p.S78= on NM_015725.4) | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV99408701; called by muse, mutect2, varscan2
- RET | c.1095G>A p.S365= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs201992974, COSV100393912, COSV100394512; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNF139 | c.120C>T p.S40= | Silent (SNP) | VAF 70/177 reads (40%) | catalogued as rs964574270, COSV100337883; called by muse, mutect2, varscan2
- RNF25 | c.888C>T p.T296= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV99829079; called by muse, mutect2, varscan2
- RPTN | c.2325C>T p.T775= | Silent (SNP) | VAF 308/603 reads (51%) | catalogued as rs763042064, COSV60167054; called by muse, mutect2, varscan2
- SBK1 | c.282C>T p.F94= | Silent (SNP) | VAF 59/146 reads (40%) | catalogued as COSV59398285; called by muse, mutect2, varscan2
- SCN10A | c.1872C>T p.L624= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as rs375858081; ClinVar: likely benign; called by muse, mutect2
- SCN5A | c.1215G>A p.V405= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100349114; called by muse, mutect2, varscan2
- SERPINB13 | c.990C>T p.F330= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99501099; called by muse, mutect2, varscan2
- SGSM3 | c.1462C>T p.L488= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV99960512; called by muse, mutect2, varscan2
- SHANK2 | c.2163G>A p.R721= | Silent (SNP) | VAF 124/140 reads (89%) | catalogued as COSV99574720; called by muse, mutect2, varscan2
- SLC22A9 | c.1140C>T p.F380= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV54165816; called by muse, mutect2, varscan2
- SLC25A19 | c.225G>A p.P75= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as rs150239035; called by muse, mutect2, varscan2
- SLC27A6 | c.507C>T p.I169= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs745715326, COSV99323021; called by muse, mutect2, varscan2
- SLCO1B3 | c.1278C>T p.F426= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV53934500; called by muse, mutect2, varscan2
- SLITRK1 | c.546C>T p.L182= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs771483350, COSV65674380, COSV65677407; called by muse, mutect2, varscan2
- SMARCD2 | c.1395G>A p.Q465= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV99856504; called by muse, mutect2, varscan2
- SPG11 | c.6060C>T p.L2020= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99968988; called by muse, mutect2, varscan2
- SRFBP1 | c.1101C>T p.S367= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV100232806, COSV59584693; called by muse, mutect2, varscan2
- SUZ12 | c.1575C>T p.I525= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as COSV100496730, COSV100496940; called by muse, mutect2, varscan2
- SYNE2 | c.3801C>T p.S1267= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs764160561, COSV100647992; called by muse, mutect2, varscan2
- TFAP4 | c.735C>T p.S245= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as rs1446651086, COSV99200074; called by muse, mutect2, varscan2
- TMEM150C | c.295C>T p.L99= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as COSV101497313; called by muse, mutect2, varscan2
- TMEM41B | c.651C>T p.I217= | Silent (SNP) | VAF 76/197 reads (39%) | catalogued as COSV55154868; called by muse, mutect2, varscan2
- TNS2 | c.2064C>T p.Y688= (on ENST00000314250 / NM_170754.4; = p.Y698= on NM_015319.2) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100036778, COSV56856406; called by muse, mutect2
- TNXB | c.10416G>A p.E3472= (on ENST00000647633; = p.E3225= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV100926424; called by muse, mutect2, varscan2
- TOX2 | c.864C>T p.I288= (on ENST00000358131 / NM_001098798.2; = p.I237= on NM_032883.3) | Silent (SNP) | VAF 63/91 reads (69%) | catalogued as rs200547615, COSV57891049; called by muse, mutect2, varscan2
- TRAPPC8 | c.2616C>T p.V872= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV99351472; called by muse, mutect2, varscan2
- TRAT1 | c.357G>A p.G119= | Silent (SNP) | VAF 30/42 reads (71%) | catalogued as COSV99849344; called by muse, mutect2, varscan2
- TRBV27 | c.279C>T p.F93= | Silent (SNP) | VAF 39/67 reads (58%) | called by muse, mutect2, varscan2
- TTN | c.51093C>T p.A17031= (on ENST00000591111; = p.A9607= on NM_003319.4) | Silent (SNP) | VAF 70/158 reads (44%) | catalogued as COSV100618770; called by muse, mutect2, varscan2
- UBAP2L | c.378G>A p.R126= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99671621; called by muse, mutect2, varscan2
- UGT2B11 | c.1548C>T p.F516= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV101485260; called by muse, mutect2, varscan2
- UHRF1BP1 | c.4207C>T p.L1403= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV99512045; called by muse, mutect2, varscan2
- VARS1 | c.2922C>T p.S974= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100791827; called by muse, mutect2, varscan2
- WDR81 | c.5811C>T p.I1937= (on ENST00000409644 / NM_001163809.2; = p.I886= on NM_152348.4) | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs1422617679, COSV100489005; called by muse, mutect2, varscan2
- XKR3 | c.1101G>A p.G367= | Silent (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- ZBTB26 | c.945A>C p.R315= | Silent (SNP) | VAF 92/110 reads (84%) | catalogued as COSV101021111; called by muse, mutect2, varscan2
- ZC3H7B | c.1614C>T p.T538= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as rs1222138301, COSV100687463; called by muse, mutect2, varscan2
- ZDHHC5 | c.678G>A p.R226= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99762474; called by muse, mutect2, varscan2
- ZIM2 | c.912G>A p.K304= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs777513840, COSV55645894; called by muse, mutect2, varscan2
- ZNF131 | c.654C>T p.T218= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100185553; called by muse, mutect2, varscan2
- ZNF214 | c.243G>A p.Q81= | Silent (SNP) | VAF 160/409 reads (39%) | catalogued as COSV99547497; called by muse, mutect2, varscan2
- ZNF592 | c.732C>T p.F244= | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as COSV100245938; called by muse, mutect2, varscan2
- ZP1 | c.1266G>A p.G422= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV99612582; called by muse, mutect2, varscan2
- FRMPD2B | n.852C>T | RNA (SNP) | VAF 5/27 reads (19%) | called by mutect2, varscan2
- GLYATL1 | c.-151G>A | 5'UTR (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100265419; called by muse, mutect2
- MIR514A1 | n.21C>T | RNA (SNP) | VAF 87/101 reads (86%) | catalogued as rs782379159; called by muse, mutect2, varscan2
- NACA | c.70+3517C>T | Intron (SNP) | VAF 48/492 reads (10%) | catalogued as rs1452948620, COSV100771411; called by muse, mutect2
- NLRP12 | chr19:53788758 G>A | 3'Flank (SNP) | VAF 6/14 reads (43%) | catalogued as rs1376453582; called by muse, mutect2, varscan2
- PAK6 | c.-117-730G>A | Intron (SNP) | VAF 8/13 reads (62%) | catalogued as rs1015338196, COSV99544668; called by muse, mutect2
- PALM2AKAP2 | c.400+6888C>A | Intron (SNP) | VAF 145/163 reads (89%) | catalogued as COSV100093251; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.400+6889C>T | Intron (SNP) | VAF 145/160 reads (91%) | catalogued as rs267602081, COSV100093253, COSV57122059; called by muse, mutect2, varscan2
- SCN2A | c.606-143G>A | Intron (SNP) | VAF 47/120 reads (39%) | catalogued as rs1050583868, COSV51838120; called by muse, mutect2, varscan2
